MMRF case MMRF_2367 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/73f727a8-d967-4fd2-824a-3b37e2c02271

Demographics
Sex at birth: male; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.4 years (25,729 days); ISS stage: I; Days to last known disease status: 814 days (2.2 years); Days to last follow up: 814 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 0): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.53 mg/dL; Immunoglobulin G 6.69 g/L; Immunoglobulin A 15.9 g/L; Immunoglobulin M 0.62 g/L; Beta 2 Microglobulin 3.3 µg/mL; Hemoglobin 9.36 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.14 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.45 mmol/L; Albumin 36 g/L; Total Protein 7.5 g/dL; Glucose 5.61 mmol/L.
- Day 93 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.53 mg/dL; Immunoglobulin G 3.8 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.78 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 5.2 g/dL; Glucose 6.05 mmol/L.
- Day 163 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Immunoglobulin G 4.04 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.68 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 5.2 g/dL; Glucose 5.78 mmol/L.
- Day 254 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 4.88 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.38 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.94 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 5.4 g/dL; Glucose 6.27 mmol/L.
- Day 432 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.59 mg/dL; Immunoglobulin G 7 g/L; Immunoglobulin A 1.51 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.37 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 5.7 g/dL; Glucose 5.39 mmol/L.
- Day 541 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.43 mg/dL; Immunoglobulin G 8.37 g/L; Immunoglobulin A 2.2 g/L; Immunoglobulin M 0.38 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.99 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 34 g/L; Total Protein 6.1 g/dL; Glucose 6.44 mmol/L.
- Day 611 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.51 mg/dL; Immunoglobulin G 9.35 g/L; Immunoglobulin A 2.54 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 8.99 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.78 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 5.61 mmol/L.
- Day 691 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 7.57 g/L; Immunoglobulin A 1.48 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.05 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 6.33 mmol/L.
- Day 814 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.78 mg/dL; Immunoglobulin G 7.12 g/L; Immunoglobulin A 2.06 g/L; Immunoglobulin M 1.03 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.31 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 5.94 mmol/L.

Other clinical attributes
- Day -6: Weight: 92 kg; Height: 182 cm.

Family history
- Relative with cancer history: yes; Relationship type: Maternal Grandmother; Relationship primary diagnosis: Multiple Myeloma; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2367_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2367_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
